CCDI case PBBMKD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2dee4582-d2f1-47cd-85c1-c09d84ceaf66

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.2 years (1,891 days).

Biospecimens (3 samples)
- Sample 0DCDMT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCDMV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCDN5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
